Somatic mutation profile of tumor specimen TCGA-TS-A8AV-01A (aliquot TCGA-TS-A8AV-01A-12D-A39R-32) from TCGA case TCGA-TS-A8AV, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Fibrous mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 56.0 years (20,437 days).
Specimen TCGA-TS-A8AV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5b9e17d-6688-4131-bebb-3be3751d4d80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A8AV-10A (Blood Derived Normal), aliquot TCGA-TS-A8AV-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fa389f8-9f0d-482e-8f79-09c11f5537a5

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD9 | c.1377G>C p.Q459H | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); called by muse, mutect2
- ELFN2 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EPHA7 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- LATS2 | c.2900T>G p.L967R | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
